Somatic mutation profile of tumor specimen 0DDKHW from CCDI case PBBNTU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.9 years (5,803 days).
Specimen 0DDKHW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08a41cb6-5add-4e4a-b1ea-f0713e616f51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDKHZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d0bb58d-2524-4e27-a54c-8cfb6f30c469

The open-access MAF lists 31 somatic variants for this specimen: 17 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 11, Missense Mutation 10, Nonsense Mutation 2, 5'UTR 2, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXIN2 | c.1994dup p.N666Qfs*41 | Frame Shift Ins (INS) | VAF 120/316 reads (38%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 311/676 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- ADAM21 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 106/701 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV50789103; called by muse, mutect2, varscan2
- EDA2R | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 236/565 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.025); catalogued as COSV53631756; called by muse, mutect2, varscan2
- GRIA2 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 191/1175 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV52388109; called by muse, mutect2, varscan2
- GYG1 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 373/892 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs138596591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KBTBD6 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 122/263 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV65271889; called by muse, mutect2, varscan2
- OR2L2 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 82/497 reads (16%) | catalogued as rs546778867, COSV63547603; called by muse, mutect2, varscan2
- PEX16 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 55/751 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.331); catalogued as rs376763841; called by muse, mutect2
- PIEZO2 | c.5644G>A p.E1882K | Missense Mutation (SNP) | VAF 186/464 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1299401088; called by muse, mutect2, varscan2
- TUT1 | c.2344del p.R782Vfs*33 | Frame Shift Del (DEL) | VAF 88/188 reads (47%) | catalogued as COSV53469375; called by mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 40/1179 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- FOXF2 | c.563C>A p.S188* | Nonsense Mutation (SNP) | VAF 25/344 reads (7%) | called by muse, mutect2
- IDH1 | c.851-7C>G | Splice Region (SNP) | VAF 237/598 reads (40%) | called by muse, mutect2, varscan2
- PTCH1 | c.2796_2800dup p.Y934Sfs*30 | Frame Shift Ins (INS) | VAF 243/561 reads (43%) | called by mutect2, varscan2
- PTCH1 | c.1375_1379del p.R459Gfs*36 | Frame Shift Del (DEL) | VAF 216/506 reads (43%) | called by mutect2, varscan2
- RNF213 | c.7645A>G p.M2549V | Missense Mutation (SNP) | VAF 142/339 reads (42%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTN1 | c.2296C>T p.L766= | Silent (SNP) | VAF 50/362 reads (14%) | called by muse, mutect2, varscan2
- DAB1 | c.486T>C p.Y162= | Silent (SNP) | VAF 80/1189 reads (7%) | catalogued as rs1325338539; called by muse, mutect2
- GGA1 | c.1650C>T p.T550= | Silent (SNP) | VAF 242/597 reads (41%) | catalogued as rs779866431; called by mutect2, varscan2
- KBTBD8 | c.501C>T p.L167= | Silent (SNP) | VAF 400/985 reads (41%) | catalogued as rs537998197; called by muse, mutect2, varscan2
- KLHL9 | c.1800C>T p.N600= | Silent (SNP) | VAF 28/979 reads (3%) | called by muse, mutect2
- OR4Q3 | c.777C>A p.I259= | Silent (SNP) | VAF 40/792 reads (5%) | catalogued as COSV100057300; called by muse, mutect2
- RREB1 | c.588G>A p.Q196= | Silent (SNP) | VAF 54/1370 reads (4%) | called by muse, mutect2
- RYR1 | c.5724A>G p.K1908= | Silent (SNP) | VAF 38/570 reads (7%) | catalogued as COSV62103704; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 52/1274 reads (4%) | called by muse, mutect2
- TENM2 | c.5229C>T p.D1743= (on ENST00000518659 / NM_001122679.2; = p.D1504= on NM_001080428.3) | Silent (SNP) | VAF 182/439 reads (41%) | catalogued as rs1263409251; called by muse, mutect2, varscan2
- THSD7B | c.2643G>A p.T881= | Silent (SNP) | VAF 366/979 reads (37%) | catalogued as rs191103781; called by muse, mutect2, varscan2
- ACLY | c.-68T>C | 5'UTR (SNP) | VAF 135/368 reads (37%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 36/276 reads (13%) | called by muse, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 20/588 reads (3%) | called by muse, mutect2
